Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4723, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4723-01A (Primary Tumor).

[page 1 of 4]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: The patient is a [REDACTED] man who presents with hoarseness, and was found to have a largely right sided laryngeal lesion. The biopsy confirmed the squamous cell carcinoma. A CT scan shows T4 lesion with direct invasion through the thyroid cartilage.

PROCEDURE: Total laryngectomy, bilateral neck dissection.

SPECIFIC CLINICAL QUESTION: Margin, lymph nodes.

OUTSIDE TISSUE DIAGNOSIS: Yes – squamous cell carcinoma.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

FINAL DIAGNOSIS:

LARYNX, LEFT AND RIGHT CERVICAL LYMPH NODES, LEVEL 2-4, RIGHT THYROID, TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTION, RIGHT THYROID LOBECTOMY –

- A. INVASIVE TRANSGLOTTIC SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 3.8 CM INVADING THROUGH THYROID CARTILAGE AND INTO ANTERIOR SOFT TISSUE.
- B. NO PERINEURAL OR ANGIOLYMPHATIC INVASION SEEN.
- C. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- D. THIRTY-SIX RIGHT AND NINETEEN LEFT CERVICAL LYMPH NODES, FREE OF TUMOR.
- E. PATHOLOGIC STAGE pT4a, N0, MX.
- F. RIGHT THYROID GLAND WITH NO SIGNIFICANT PATHOLOGIC CHANGES.

[REDACTED]

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, initials [REDACTED], medical record # and "larynx, bilateral neck levels 2-4, right hemi thyroid". It consists of a total laryngectomy specimen (15.0 x 7.5 x 5.8 cm) including hyoid bone (3.0 x 0.5 x 0.5 cm), larynx from epiglottis to tracheal ring (7.5 x 2.0 x 2.0 cm), soft tissue of the left neck (8.0 x 2.5 x 2.0 cm), soft tissue of the right neck (8.5 x 2.5 x 2.0 cm), and right thyroid (4.8 x 4.5 x 2.0 cm). There is a transglottic irregular tan-pink, soft, fungating mass (3.8 x 3.8 x 2.0 cm). The mass is centered on the anterior glottis and involves supra-glottis and subglottis, invades between cricoid

[page 2 of 4]
Pathology Report

cartilage and thyroid cartilage into deep anterior soft tissue (0.6 cm from anterior soft tissue margin), laterally abuts the posterior aspect of the right thyroid, without grossly obvious invasion, and is 1.0 cm from aryepiglottic mucosal margin and 2.0 cm from superior mucosal margin. The anterior surface is covered by red-brown skeletal muscles, which are grossly unremarkable. No parathyroid glands identified near right thyroid lobe. The right thyroid gland is soft gelatinous beefy red and unremarkable. The sectioning of the bilateral neck soft tissue demonstrate right level 2 lymph nodes, ranging from 0.2 to 2.6 cm, right level 3 lymph nodes, ranging from 0.6 to 3.0 cm, right level 3 lymph nodes, ranging from 0.3 to 1.1 cm, left level 2 lymph nodes, ranging from 0.2 to 1.8 cm, left level 3 lymph nodes, ranging from 0.5 to 2.2 cm, and left level 4 lymph nodes, ranging from 0.2 to 1.0 cm. Representative sections are procured for the tissue banking. Digital images are taken. Anterior soft tissue margins are inked. Representative sections are submitted as follows:

- A – right aryepiglottic margin, perpendicular section
- B – left aryepiglottic margin, perpendicular section
- C – epiglottis (superior) margin, perpendicularly sectioned
- D – tracheal ring margin
- E – transglottic section of the tumor (right)
- F – tumor with thyroid cartilage
- G – tumor abutting deep anterior soft tissue
- H – tumor with thyroid
- I – transglottic section of the tumor (left)
- J – lymph nodes, right level 2
- K – lymph nodes, right level 2
- L – lymph nodes, right level 2
- M – one lymph node, bisected
- N – lymph nodes, right level 3
- O – one lymph node, right level 3, bisected
- P – lymph nodes, right level 4
- Q – lymph nodes, right level 4
- R – lymph nodes, left level 2
- S – lymph nodes, left level 2
- T – lymph nodes, left level 3
- U – lymph nodes, left level 3
- V – lymph nodes, left level 4
- W – tumor with thyroid
- X – normal thyroid
- Y – 1AES – frozen section remnant

INTRAOPERATIVE CONSULTATION:

1AES: LARYNX, ANTERIOR SOFT TISSUE MARGIN (frozen section) –

A. BENIGN.

B. MARGINS ARE FREE OF TUMOR.

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED], as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED]

[page 3 of 4]
Pathology Report

to a maximum of [REDACTED]

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - LARYNX RESECTIONS

TYPE OF LARYNGECTOMY:	Total
TUMOR LOCATION:	Midline
ATTACHED STRUCTURES:	Neck dissection, Thyroid
TUMOR LOCATION/SEGMENT:	Transglottic
TUMOR SIZE:	Maximum dimension: 3.8 cm
HISTOLOGIC TYPE OF TUMOR:	Squamous cell carcinoma
HISTOLOGIC GRADE:	Moderately differentiated
STRUCTURES INVOLVED BY TUMOR:	True cord, Anterior commissure, False cord, Ventricle, Epiglottis, Thyroid cartilage, Extralaryngeal soft tissue
LYMPH NODES POSITIVE:	Number of lymph nodes positive: 0
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 55
EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES	No
INTRA-PERINEURAL INVASION:	Absent
VASCULAR INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	Free (2 mm or more)
T STAGE, PATHOLOGIC:	Glottis, pT4a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Larynx Bilateral Neck Levels 2-4 Right Hemi Thyroid

Taken: [REDACTED]

Stain/cnt	Block
-----------	-------

H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J
H&E x 1	K
H&E x 1	L
H&E x 1	M
H&E x 1	N
H&E x 1	O
H&E x 1	P
H&E x 1	Q
H&E x 1	R

[page 4 of 4]
Pathology Report

H&E x 1	S
H&E x 1	T
H&E x 1	U
H&E x 1	V
H&E x 1	W
H&E x 1	X
H&E x 1	Y

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file 7e641b6f-c6aa-4e85-8ee0-261ad6f1d612 (TCGA-CN-4723.FDBDDD45-1E22-4B87-996A-4DF432E1FAFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).